Somatic mutation profile of tumor specimen TCGA-AR-A2LO-01A (aliquot TCGA-AR-A2LO-01A-31D-A18P-09) from TCGA case TCGA-AR-A2LO, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 46.8 years (17,080 days).
Specimen TCGA-AR-A2LO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd7f6b49-f072-4824-bbf1-6c761ad8ee55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A2LO-10A (Blood Derived Normal), aliquot TCGA-AR-A2LO-10A-01D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5489f385-84da-4816-b251-2cb1dddd88d4

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 13, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP63 | c.1034T>G p.L345R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.919); catalogued as COSV59678076; called by muse, mutect2, varscan2
- COL5A1 | c.931A>T p.T311S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.009); catalogued as COSV65672581; called by muse, mutect2, varscan2
- KIF16B | c.2941C>G p.R981G | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61705200, COSV61710672; called by muse, mutect2, varscan2
- NEU4 | c.628C>T p.R210C (on ENST00000391969 / NM_001167602.3; = p.R222C on NM_080741.4) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs370002261, COSV57991448; called by muse, mutect2, varscan2
- PIK3CA | c.1559A>T p.D520V | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.136); catalogued as COSV99844419; called by muse, mutect2
- ROBO4 | c.1274G>T p.G425V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60626309; called by muse, mutect2, varscan2
- RYR2 | c.11081T>A p.I3694N | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63684086, COSV63700930; called by muse, mutect2, varscan2
- TMEM101 | c.604C>A p.L202I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as COSV99243999; called by muse, mutect2
- TRPM5 | c.2095C>T p.R699W | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs775413241, COSV50149700; called by muse, mutect2, varscan2
- VIPR2 | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.031); catalogued as COSV100058365; called by muse, mutect2
- ZNF789 | c.393G>T p.K131N | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV100508023; called by muse, mutect2
- ZNF835 | c.103C>G p.P35A | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.119); catalogued as COSV101606411; called by muse, mutect2
- ZXDB | c.2219C>T p.S740L | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66493114; called by muse, mutect2, varscan2
- RB1CC1 | c.543C>A p.S181= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV50260172; called by muse, mutect2, varscan2
- SLC6A8 | c.1515C>T p.D505= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs151335200, COSV53473540; ClinVar: likely benign; called by muse, mutect2
